Somatic mutation profile of tumor specimen ALCH-B1S8-TTP1-A (aliquot ALCH-B1S8-TTP1-A-1-0-D-A76B-36) from ALCHEMIST case ALCH-B1S8, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 81.3 years (29,708 days).
Specimen ALCH-B1S8-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef7b5294-e57c-498c-b14a-5473fb6696a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1S8-NB1-A (Blood Derived Normal), aliquot ALCH-B1S8-NB1-A-1-0-D-A76B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/51ee3a18-1cf6-490f-bdb2-66894a266540

The open-access MAF lists 208 somatic variants for this specimen: 150 protein-altering or splice-affecting, 44 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 129, Silent 44, Nonsense Mutation 9, Splice Site 7, Intron 5, 3'UTR 3, Frame Shift Del 3, 5'UTR 2, Translation Start Site 1, RNA 1, IGR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC244197.3 | c.770G>T p.R257L | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs113993946, CM128959, CM930422, CM950672, CX149681; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.310C>T p.Q104* | Nonsense Mutation (SNP) | VAF 5/63 reads (8%) | hotspot (GDC flag); catalogued as rs1567555934, COSV52694629; ClinVar: pathogenic; called by muse, mutect2
- ADAMTS16 | c.1417C>T p.P473S | Missense Mutation (SNP) | VAF 30/362 reads (8%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as rs569485607; called by muse, mutect2
- ADGRG4 | c.3275C>T p.T1092M | Missense Mutation (SNP) | VAF 26/392 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs767463033, COSV54965093; called by muse, mutect2
- ADGRL3 | c.4036G>A p.E1346K (on ENST00000506720 / NM_001322402.2; = p.E1235K on NM_015236.6) | Missense Mutation (SNP) | VAF 19/488 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.322); catalogued as rs1233622462, COSV72230894; called by muse, mutect2
- ALG10B | c.575G>T p.W192L | Missense Mutation (SNP) | VAF 39/614 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58145036; called by muse, mutect2
- ARHGAP42 | c.184C>T p.Q62* | Nonsense Mutation (SNP) | VAF 21/245 reads (9%) | catalogued as COSV53981378; called by muse, mutect2
- CHRNG | c.1139G>T p.G380V | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV67315672; called by muse, mutect2
- COL15A1 | c.719C>T p.S240F | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.553); catalogued as COSV66641275; called by muse, mutect2
- COL21A1 | c.560C>G p.S187W | Missense Mutation (SNP) | VAF 20/256 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55180907; called by muse, mutect2
- CPD | c.1208C>A p.S403* | Nonsense Mutation (SNP) | VAF 10/252 reads (4%) | catalogued as COSV56710351; called by muse, mutect2
- DST | c.18556C>A p.P6186T (on ENST00000361203 / NM_001374722.1; = p.P3883T on NM_015548.5) | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.881); catalogued as COSV99758441; called by muse, mutect2
- DZIP1 | c.2142G>C p.K714N (on ENST00000347108; = p.K695N on NM_014934.5) | Missense Mutation (SNP) | VAF 46/295 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs1472004530; called by muse, mutect2, varscan2
- EPHA6 | c.714G>T p.Q238H | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.807); catalogued as COSV67585762; called by muse, mutect2
- ERCC6 | c.544-1G>T p.X182_splice | Splice Site (SNP) | VAF 20/514 reads (4%) | catalogued as CS099996; called by muse, mutect2
- EVA1A | c.346G>T p.E116* | Nonsense Mutation (SNP) | VAF 20/330 reads (6%) | catalogued as COSV52057741; called by muse, mutect2
- F13A1 | c.1685C>A p.T562N | Missense Mutation (SNP) | VAF 28/328 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53566178; called by muse, mutect2
- FAT4 | c.8601C>G p.I2867M | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.648); catalogued as COSV100627093; called by muse, mutect2
- FOXD1 | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT tolerated, low confidence (0.6); PolyPhen possibly damaging (0.602); catalogued as rs1196832423; called by muse, mutect2
- FSTL5 | c.544C>G p.Q182E | Missense Mutation (SNP) | VAF 11/191 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as COSV60184295; called by muse, mutect2
- GSG1L | c.488C>A p.S163Y (on ENST00000447459 / NM_001109763.2; = p.S8Y on NM_144675.2) | Missense Mutation (SNP) | VAF 10/177 reads (6%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.991); catalogued as COSV66582179; called by muse, mutect2
- HDAC9 | c.942T>G p.D314E | Missense Mutation (SNP) | VAF 12/317 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1158635428; called by muse, mutect2
- IGHV3-23 | c.198G>T p.W66C | Missense Mutation (SNP) | VAF 39/722 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.236); catalogued as rs1164728836; called by muse, mutect2
- KAT14 | c.1753G>A p.V585M | Missense Mutation (SNP) | VAF 14/377 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1332960643; called by muse, mutect2
- MAMLD1 | c.1591C>A p.P531T | Missense Mutation (SNP) | VAF 54/488 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV99476379; called by muse, varscan2
- MATN4 | c.1648G>T p.D550Y (on ENST00000372754; = p.D509Y on NM_003833.4) | Missense Mutation (SNP) | VAF 18/256 reads (7%) | PolyPhen probably damaging (1); catalogued as COSV100637186; called by muse, mutect2
- MED12L | c.3019C>T p.R1007C | Missense Mutation (SNP) | VAF 14/492 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs866960428, COSV56388799; called by muse, mutect2
- MUC16 | c.30935C>A p.P10312H | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.279); catalogued as COSV101201517; called by muse, mutect2
- NBPF9 | c.2129C>T p.S710L | Missense Mutation (SNP) | VAF 44/764 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.214); catalogued as rs1407100896; called by muse, mutect2
- NLRP4 | c.163C>A p.L55I | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56711401; called by muse, mutect2
- NUP155 | c.3598G>A p.E1200K (on ENST00000231498 / NM_153485.3; = p.E1141K on NM_004298.4) | Missense Mutation (SNP) | VAF 32/506 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV51526779; called by muse, mutect2
- OCA2 | c.50T>A p.V17E | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.149); catalogued as rs1237182917, COSV100668768; called by muse, mutect2
- OR14K1 | c.595G>T p.A199S | Missense Mutation (SNP) | VAF 58/576 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.053); catalogued as COSV51721871; called by muse, mutect2
- RBFOX1 | c.412G>T p.G138C | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV60985956; called by muse, mutect2
- RBM10 | c.199G>T p.E67* | Nonsense Mutation (SNP) | VAF 10/92 reads (11%) | catalogued as COSV61312458; called by muse, mutect2, varscan2
- RIMS2 | c.3182del p.M1061Rfs*7 (on ENST00000666250 / NM_001348490.2; = p.M869Rfs*7 on NM_014677.5 and 7 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 42/396 reads (11%) | catalogued as COSV51721583; called by mutect2, varscan2
- ROR2 | c.488A>T p.N163I | Missense Mutation (SNP) | VAF 36/616 reads (6%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as rs779925623; called by muse, mutect2
- RTL4 | c.437C>A p.P146H | Missense Mutation (SNP) | VAF 22/261 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.554); catalogued as COSV100465722, COSV61206926, COSV61207477; called by muse, mutect2
- RTL9 | c.1946T>C p.V649A | Missense Mutation (SNP) | VAF 28/324 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1164764556; called by muse, mutect2
- SLC17A6 | c.360C>A p.D120E | Missense Mutation (SNP) | VAF 28/392 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.771); catalogued as COSV54136018; called by muse, mutect2
- SLC39A4 | c.1399G>T p.E467* (on ENST00000301305 / NM_001374839.1; = p.E442* on NM_017767.3) | Nonsense Mutation (SNP) | VAF 12/124 reads (10%) | catalogued as COSV52778526; called by muse, mutect2
- SLC6A5 | c.2109G>T p.M703I | Missense Mutation (SNP) | VAF 30/331 reads (9%) | SIFT tolerated (0.64); PolyPhen benign (0.01); catalogued as COSV54223840; called by muse, mutect2
- SMARCAD1 | c.1081G>A p.D361N | Missense Mutation (SNP) | VAF 19/309 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.115); catalogued as COSV62775066, COSV62775332; called by muse, mutect2
- SPANXN4 | c.131C>A p.T44K | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.563); catalogued as rs757147153; called by muse, mutect2
- SRPK3 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 15/186 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs782314376; called by muse, mutect2, varscan2
- STAB2 | c.4691G>T p.G1564V | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66333798; called by muse, mutect2
- STIM1 | c.1940T>A p.L647Q | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.907); catalogued as rs1372331507; called by muse, mutect2
- UGT1A9 | c.259G>T p.D87Y | Missense Mutation (SNP) | VAF 28/271 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV60832299, COSV60840417; called by muse, mutect2
- WDFY4 | c.5779G>C p.E1927Q | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as COSV55424962; called by muse, mutect2
- WDR49 | c.1903C>A p.P635T (on ENST00000308378 / NM_001366158.1; = p.P976T on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs753705042, COSV57704772, COSV57717281; called by muse, mutect2
- WDR49 | c.505G>A p.G169R (on ENST00000308378 / NM_001366158.1; = p.G510R on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/199 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV100392341, COSV57714555; called by muse, mutect2
- ZNF469 | c.7265G>T p.G2422V (on ENST00000437464; = p.G2450V on NM_001367624.2) | Missense Mutation (SNP) | VAF 19/220 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs1471829166; called by muse, mutect2
- ABCB11 | c.2744G>C p.G915A | Missense Mutation (SNP) | VAF 22/256 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); called by muse, mutect2
- ABCC5 | c.3049del p.A1017Qfs*19 | Frame Shift Del (DEL) | VAF 29/288 reads (10%) | called by mutect2, pindel, varscan2
- ACTR1B | c.85C>A p.Q29K | Missense Mutation (SNP) | VAF 32/344 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.345); called by muse, mutect2
- ADCY1 | c.2956G>A p.A986T | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADGRL1 | c.2008G>T p.A670S (on ENST00000340736 / NM_001008701.3; = p.A665S on NM_014921.5) | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.61); PolyPhen benign (0.06); called by muse, mutect2
- ARHGDIG | c.339G>T p.G113= | Splice Region (SNP) | VAF 17/201 reads (8%) | called by muse, mutect2
- BDKRB1 | c.210C>G p.N70K | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2
- CALR3 | c.1093T>C p.S365P | Missense Mutation (SNP) | VAF 12/368 reads (3%) | SIFT tolerated (0.27); PolyPhen benign (0.02); called by muse, mutect2
- CCDC171 | c.2571G>T p.Q857H | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); called by muse, mutect2
- CENPB | c.1417G>T p.A473S | Missense Mutation (SNP) | VAF 14/151 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.074); called by muse, mutect2
- CEP128 | c.1796G>T p.S599I | Missense Mutation (SNP) | VAF 28/283 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CHAT | c.1635-2A>T p.X545_splice | Splice Site (SNP) | VAF 17/370 reads (5%) | called by muse, mutect2
- CHML | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2
- COL4A1 | c.3298G>T p.G1100W | Missense Mutation (SNP) | VAF 78/870 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CRACD | c.1325G>A p.R442K | Missense Mutation (SNP) | VAF 12/291 reads (4%) | SIFT tolerated (0.68); PolyPhen benign (0.022); called by muse, mutect2
- CSF2RB | c.277C>A p.P93T | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.536); called by muse, mutect2
- CYP3A7 | c.548T>C p.V183A | Missense Mutation (SNP) | VAF 58/614 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); called by muse, mutect2
- DGKK | c.1997C>A p.T666K | Missense Mutation (SNP) | VAF 26/394 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.122); called by muse, mutect2
- DLGAP2 | c.1581C>A p.C527* | Nonsense Mutation (SNP) | VAF 12/112 reads (11%) | called by muse, mutect2
- DMD | c.10381C>T p.P3461S | Missense Mutation (SNP) | VAF 22/400 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.561); called by muse, mutect2
- DNAH10 | c.6996G>T p.K2332N (on ENST00000409039; = p.K2271N on NM_207437.3) | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.549); called by muse, varscan2
- DYSF | c.1569C>G p.I523M | Missense Mutation (SNP) | VAF 14/256 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.221); called by muse, mutect2
- EHMT2 | c.251G>T p.G84V | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.036); called by muse, varscan2
- ERICH6B | c.1307C>A p.P436H | Missense Mutation (SNP) | VAF 24/239 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.015); called by muse, mutect2
- EXT2 | c.2061G>T p.M687I (on ENST00000343631; = p.M720I on NM_000401.3) | Missense Mutation (SNP) | VAF 20/621 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.397); called by muse, mutect2
- F13B | c.1355-1G>C p.X452_splice | Splice Site (SNP) | VAF 7/78 reads (9%) | called by muse, mutect2
- FAT2 | c.3522C>G p.F1174L | Missense Mutation (SNP) | VAF 17/390 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- FAT2 | c.3341C>T p.S1114F | Missense Mutation (SNP) | VAF 16/344 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); called by muse, mutect2
- GMPPA | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 24/326 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.345); called by muse, mutect2
- GNAS | c.1275C>A p.F425L | Missense Mutation (SNP) | VAF 25/232 reads (11%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- HACL1 | c.227+1G>T p.X76_splice | Splice Site (SNP) | VAF 19/319 reads (6%) | called by muse, mutect2
- IGSF21 | c.155G>T p.G52V | Missense Mutation (SNP) | VAF 18/271 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ITGA3 | c.1505G>A p.S502N | Missense Mutation (SNP) | VAF 16/216 reads (7%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.863); called by muse, mutect2
- KALRN | c.3677G>A p.R1226K | Missense Mutation (SNP) | VAF 24/314 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); called by muse, mutect2
- KCNH5 | c.1032T>A p.Y344* | Nonsense Mutation (SNP) | VAF 47/348 reads (14%) | called by muse, mutect2, varscan2
- KIF26B | c.884C>A p.A295D | Missense Mutation (SNP) | VAF 30/292 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2
- L1CAM | c.1077G>T p.R359S | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.03); called by muse, mutect2
- LRP1B | c.2048G>T p.G683V | Missense Mutation (SNP) | VAF 49/619 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAGEB6B | c.438G>T p.Q146H | Missense Mutation (SNP) | VAF 42/464 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.756); called by muse, mutect2
- MKI67 | c.5815A>G p.R1939G | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); called by muse, mutect2
- MXRA5 | c.3163C>A p.L1055M | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.36); called by muse, mutect2
- MYH11 | c.4408G>C p.E1470Q | Missense Mutation (SNP) | VAF 13/224 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2
- MYH8 | c.3365G>T p.G1122V | Missense Mutation (SNP) | VAF 28/394 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2
- MYH8 | c.1135G>T p.D379Y | Missense Mutation (SNP) | VAF 29/704 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- MYLK3 | c.1711A>G p.N571D | Missense Mutation (SNP) | VAF 23/281 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- NALCN | c.4804C>A p.Q1602K | Missense Mutation (SNP) | VAF 13/365 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0.044); called by muse, mutect2
- NCF4 | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 23/316 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NOBOX | c.683C>A p.A228D | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NUDT11 | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, mutect2
- OGFOD3 | c.489-2A>T p.X163_splice | Splice Site (SNP) | VAF 14/120 reads (12%) | called by muse, mutect2
- OR2L8 | c.153C>A p.D51E | Missense Mutation (SNP) | VAF 22/298 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.242); called by muse, mutect2
- OR4L1 | c.835A>G p.T279A | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OR4P4 | c.115G>C p.G39R | Missense Mutation (SNP) | VAF 8/137 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.32); called by muse, mutect2
- OR8I2 | c.419T>A p.V140E | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.406); called by muse, mutect2
- PAQR9 | c.246C>A p.N82K | Missense Mutation (SNP) | VAF 6/167 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDH1 | c.703A>G p.M235V | Missense Mutation (SNP) | VAF 26/271 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.229); called by muse, mutect2
- PCK1 | c.496G>T p.V166L | Missense Mutation (SNP) | VAF 16/386 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- PEAR1 | c.1859T>A p.V620E | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2
- PGK1 | c.130G>C p.V44L | Missense Mutation (SNP) | VAF 33/502 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- PHKA2 | c.2507T>A p.V836D | Missense Mutation (SNP) | VAF 12/326 reads (4%) | SIFT tolerated (0.61); PolyPhen benign (0.006); called by muse, mutect2
- PLEC | c.11986_12008del p.Q3996* (on ENST00000322810 / NM_201380.4; = p.Q3886* on NM_000445.5) | Frame Shift Del (DEL) | VAF 6/58 reads (10%) | called by mutect2, pindel
- POU2F2 | c.1024C>T p.R342C (on ENST00000526816 / NM_001207025.3; = p.R326C on NM_002698.5) | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PRKCI | c.775G>T p.V259L | Missense Mutation (SNP) | VAF 23/227 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- PSMD11 | c.193G>T p.E65* | Nonsense Mutation (SNP) | VAF 19/255 reads (7%) | called by muse, mutect2
- RALYL | c.366-2A>T p.X122_splice | Splice Site (SNP) | VAF 12/162 reads (7%) | called by muse, mutect2
- RBM11 | c.134G>T p.R45I | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.417); called by muse, mutect2
- RXFP2 | c.426-1G>C p.X142_splice | Splice Site (SNP) | VAF 30/300 reads (10%) | called by muse, mutect2
- SALL1 | c.1850T>A p.L617Q | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.131); called by muse, mutect2
- SEC16B | c.2857G>T p.G953C | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- SEPTIN8 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 7/149 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2
- SF3B1 | c.1726G>T p.V576L | Missense Mutation (SNP) | VAF 22/286 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2
- SMAD7 | c.458A>T p.Y153F | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.012); called by muse, mutect2
- SMPD4 | c.1930G>T p.D644Y (on ENST00000409031 / NM_017951.4; = p.D615Y on NM_017751.4) | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.89); called by muse, mutect2
- SOCS6 | c.808G>T p.D270Y | Missense Mutation (SNP) | VAF 20/179 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.259); called by muse, mutect2
- SP5 | c.218G>T p.W73L | Missense Mutation (SNP) | VAF 11/143 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.076); called by muse, mutect2
- SPANXB1 | c.110G>T p.G37V | Missense Mutation (SNP) | VAF 34/1197 reads (3%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.998); called by muse, mutect2
- SRRM5 | c.1469G>T p.S490I | Missense Mutation (SNP) | VAF 14/351 reads (4%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.466); called by muse, mutect2
- SYT16 | c.9G>T p.L3F | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- TAF5L | c.684G>T p.M228I | Missense Mutation (SNP) | VAF 5/102 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TAS2R40 | c.231G>C p.E77D | Missense Mutation (SNP) | VAF 18/214 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.146); called by muse, mutect2
- TBX22 | c.1342C>A p.Q448K | Missense Mutation (SNP) | VAF 34/455 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.169); called by muse, mutect2
- TCEAL1 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 30/581 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2
- TEKT2 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 15/414 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.457); called by muse, mutect2
- TEX51 | c.448G>T p.D150Y (on ENST00000643416; = p.D126Y on NM_001322244.2) | Missense Mutation (SNP) | VAF 18/199 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TOPAZ1 | c.598G>C p.D200H | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); called by muse, mutect2
- TRAV20 | c.197A>G p.E66G | Missense Mutation (SNP) | VAF 16/348 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.073); called by muse, mutect2
- TRBC2 | c.231C>A p.S77R | Missense Mutation (SNP) | VAF 14/246 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRGV10 | c.211A>C p.K71Q | Missense Mutation (SNP) | VAF 15/556 reads (3%) | SIFT tolerated (0.62); PolyPhen benign (0.239); called by muse, mutect2
- TRMT10C | c.265G>C p.D89H | Missense Mutation (SNP) | VAF 14/301 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2
- TTN | c.102680C>T p.S34227F (on ENST00000591111; = p.S26803F on NM_003319.4) | Missense Mutation (SNP) | VAF 12/206 reads (6%) | PolyPhen possibly damaging (0.885); called by muse, mutect2
- VAX1 | c.904A>G p.N302D | Missense Mutation (SNP) | VAF 22/236 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.584); called by muse, mutect2
- ZHX2 | c.949C>A p.H317N | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); called by muse, mutect2
- ZNF221 | c.1539G>C p.K513N | Missense Mutation (SNP) | VAF 27/283 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZNF275 | c.1040G>A p.R347Q | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- ZNF460 | c.106G>T p.A36S | Missense Mutation (SNP) | VAF 17/179 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- ZNF679 | c.62T>A p.V21E | Missense Mutation (SNP) | VAF 15/189 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2
- ZNF780A | c.1769G>C p.C590S | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZSCAN25 | c.706G>T p.A236S | Missense Mutation (SNP) | VAF 28/293 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.211); called by muse, mutect2
- ACTR3B | c.1107G>A p.T369= | Silent (SNP) | VAF 33/332 reads (10%) | catalogued as COSV99753853; called by muse, mutect2, varscan2
- ADRB3 | c.243A>T p.A81= | Silent (SNP) | VAF 8/198 reads (4%) | called by muse, mutect2
- AKR1D1 | c.498G>A p.L166= | Silent (SNP) | VAF 40/414 reads (10%) | called by muse, mutect2
- ALPK3 | c.3498G>A p.K1166= | Silent (SNP) | VAF 8/189 reads (4%) | catalogued as COSV51930353; called by muse, mutect2
- AR | c.645G>T p.S215= | Silent (SNP) | VAF 14/154 reads (9%) | catalogued as rs756400174; called by muse, mutect2
- ARMC4 | c.1708C>A p.R570= | Silent (SNP) | VAF 30/388 reads (8%) | called by muse, mutect2
- ATOH8 | c.708C>T p.N236= | Silent (SNP) | VAF 9/106 reads (8%) | catalogued as rs1188519545, COSV60399628; called by muse, mutect2
- ATP2B2 | c.2442G>T p.G814= (on ENST00000352432; = p.G780= on NM_001683.5) | Silent (SNP) | VAF 12/172 reads (7%) | called by muse, mutect2
- ATP8A2 | c.2337G>A p.R779= | Silent (SNP) | VAF 12/158 reads (8%) | called by muse, mutect2
- CCDC80 | c.807C>T p.I269= | Silent (SNP) | VAF 19/474 reads (4%) | catalogued as rs1035762438, COSV52817012, COSV99244737; called by muse, mutect2
- DDX43 | c.759T>A p.V253= | Silent (SNP) | VAF 18/287 reads (6%) | called by muse, mutect2
- DNAH5 | c.12165C>T p.P4055= | Silent (SNP) | VAF 55/489 reads (11%) | catalogued as COSV54216256; called by muse, mutect2, varscan2
- FAM131B | c.489C>T p.N163= | Silent (SNP) | VAF 24/220 reads (11%) | called by muse, mutect2, varscan2
- FAM98A | c.651C>T p.V217= | Silent (SNP) | VAF 14/392 reads (4%) | called by muse, mutect2
- FBN2 | c.5409A>T p.T1803= | Silent (SNP) | VAF 18/416 reads (4%) | called by muse, mutect2
- GJB7 | c.327C>G p.L109= | Silent (SNP) | VAF 12/300 reads (4%) | catalogued as COSV51529099; called by muse, mutect2
- GPR149 | c.144G>A p.L48= | Silent (SNP) | VAF 39/668 reads (6%) | catalogued as COSV101078344; called by muse, mutect2
- GSDME | c.684G>C p.L228= | Silent (SNP) | VAF 20/513 reads (4%) | called by muse, mutect2
- HSPA9 | c.1065C>G p.V355= | Silent (SNP) | VAF 29/772 reads (4%) | called by muse, mutect2
- IMPG2 | c.1995A>C p.S665= | Silent (SNP) | VAF 12/109 reads (11%) | called by muse, mutect2, varscan2
- ITIH5 | c.2721C>A p.A907= | Silent (SNP) | VAF 14/378 reads (4%) | catalogued as COSV53662541; called by muse, mutect2
- KALRN | c.3678G>A p.R1226= | Silent (SNP) | VAF 24/311 reads (8%) | catalogued as COSV53757107; called by muse, mutect2
- KRT75 | c.1425C>T p.V475= | Silent (SNP) | VAF 18/357 reads (5%) | catalogued as COSV99359624; called by muse, mutect2
- LCE1B | c.195G>T p.G65= | Silent (SNP) | VAF 14/273 reads (5%) | catalogued as rs921399975; called by muse, mutect2
- LRRC6 | c.408A>G p.V136= | Silent (SNP) | VAF 17/139 reads (12%) | catalogued as rs762081490; ClinVar: uncertain significance / likely benign; called by mutect2, varscan2
- MATN4 | c.1647G>T p.P549= (on ENST00000372754; = p.P508= on NM_003833.4) | Silent (SNP) | VAF 18/258 reads (7%) | called by muse, mutect2
- MGMT | c.624G>A p.G208= (on ENST00000306010; = p.G177= on NM_002412.5) | Silent (SNP) | VAF 8/148 reads (5%) | catalogued as rs1409496827; called by muse, mutect2
- NPY1R | c.528C>T p.Y176= | Silent (SNP) | VAF 6/114 reads (5%) | catalogued as COSV99648426; called by muse, mutect2
- OCA2 | c.1332C>G p.T444= | Silent (SNP) | VAF 42/495 reads (8%) | called by muse, mutect2
- OR5B21 | c.309G>T p.V103= | Silent (SNP) | VAF 16/250 reads (6%) | catalogued as rs1270458928, COSV100835185; called by muse, mutect2
- PRKD3 | c.1050T>C p.N350= | Silent (SNP) | VAF 22/344 reads (6%) | called by muse, mutect2
- PURB | c.546C>T p.F182= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as rs1005171484; called by muse, mutect2, varscan2
- RASA3 | c.1086G>T p.R362= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV61867903; called by muse, mutect2, varscan2
- RYR2 | c.13122C>T p.D4374= | Silent (SNP) | VAF 16/122 reads (13%) | called by muse, varscan2
- SH3KBP1 | c.477G>T p.S159= | Silent (SNP) | VAF 25/340 reads (7%) | called by muse, mutect2
- SLC4A7 | c.1662T>C p.N554= | Silent (SNP) | VAF 13/255 reads (5%) | called by muse, mutect2
- SPON1 | c.1635G>A p.T545= | Silent (SNP) | VAF 7/102 reads (7%) | catalogued as rs782358659; called by muse, mutect2
- TENT4A | c.1704C>T p.I568= | Silent (SNP) | VAF 9/114 reads (8%) | called by muse, mutect2
- THEG | c.585G>A p.E195= | Silent (SNP) | VAF 18/255 reads (7%) | called by muse, mutect2
- TPO | c.2418C>A p.P806= | Silent (SNP) | VAF 28/213 reads (13%) | called by muse, mutect2, varscan2
- UCP1 | c.417C>A p.V139= | Silent (SNP) | VAF 42/568 reads (7%) | called by muse, mutect2
- UGT1A9 | c.258G>T p.L86= | Silent (SNP) | VAF 28/267 reads (10%) | called by muse, mutect2
- UGT2A2 | c.645T>C p.F215= | Silent (SNP) | VAF 16/284 reads (6%) | called by muse, mutect2
- USP32 | c.1053G>A p.E351= | Silent (SNP) | VAF 24/244 reads (10%) | called by muse, mutect2
- ARHGEF33 | c.-199C>T | 5'UTR (SNP) | VAF 11/202 reads (5%) | called by muse, mutect2
- BBOX1 | c.334+25T>A | Intron (SNP) | VAF 26/334 reads (8%) | called by muse, mutect2
- BMPER | c.-43C>T | 5'UTR (SNP) | VAF 20/271 reads (7%) | called by muse, mutect2
- CCDC74B | c.296-59G>A | Intron (SNP) | VAF 9/134 reads (7%) | catalogued as rs1221588157; called by muse, mutect2
- CNNM1 | c.2176+3643C>T | Intron (SNP) | VAF 14/348 reads (4%) | called by muse, mutect2
- LRRC63 | chr13:46270487 C>A | 3'Flank (SNP) | VAF 20/160 reads (13%) | called by muse, mutect2, varscan2
- PDZRN3 | c.918+33165G>A | Intron (SNP) | VAF 12/266 reads (5%) | called by muse, mutect2
- PLP2 | c.*43T>C | 3'UTR (SNP) | VAF 29/299 reads (10%) | called by muse, mutect2
- PLP2 | c.*45C>A | 3'UTR (SNP) | VAF 28/290 reads (10%) | called by muse, mutect2
- RGSL1 | c.3198-10C>G | Intron (SNP) | VAF 9/222 reads (4%) | catalogued as rs1257705256; called by muse, mutect2
- TCP10L3 | n.2732C>A | RNA (SNP) | VAF 20/358 reads (6%) | called by muse, mutect2
- TOMM20 | c.*7A>G | 3'UTR (SNP) | VAF 24/250 reads (10%) | called by muse, mutect2, varscan2
- Unknown | chr7:55699008 C>A | IGR (SNP) | VAF 7/84 reads (8%) | catalogued as rs1431228060; called by muse, mutect2
- XIAP | chrX:123860267 G>C | 5'Flank (SNP) | VAF 14/203 reads (7%) | called by muse, mutect2
